Surgical pathology report (de-identified scan), TCGA case TCGA-HL-7533, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-HL-7533-01A (Primary Tumor).

SPECIMENS:

- A. RIGHT SOFT PALATE
- B. RIGHT SOFT PALATE

SPECIMEN(S):

- A. RIGHT SOFT PALATE
- B. RIGHT SOFT PALATE

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

FSA-right soft palate: Squamous cell carcinoma called by [REDACTED]

DIAGNOSIS:

- A. SOFT PALATE, RIGHT, BIOPSY:
- INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA
- B. SOFT PALATE, RIGHT, BIOPSY:
- INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA
- SEE NOTE
- NOTE: Focally, the tumor has a papillary configuration. HPV result to follow.

GROSS DESCRIPTION:

- A. RIGHT SOFT PALATE

Received fresh is an aggregate of tan-white soft tissue with a granular appearance measuring 2 x 2 x 0.5 cm. Touch preps are performed and a portion of the specimen is submitted for frozen section diagnosis. Specimen is submitted entirely as follows:
FSA1: frozen section
A2: remainder of soft tissue
- B. RIGHT SOFT PALATE

Received fresh are pieces of pink-tan granular soft tissue in aggregate measuring 2.7 x 2.5 x 1.3 cm. HPV testing as requested and a portion is submitted for tissue procurement. Remainder of the specimen is submitted entirely in cassette B1-B3.

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Palate lesion

ADDENDUM:

High risk HPV 16/18 in-situ hybridization is positive (block B3).

Gross Dictation: Pathologist, [REDACTED]
Microscopic/Diagnostic Dictation: Pathologist [REDACTED]
Final Review: Pathologist, [REDACTED]
Final: Pathologist, [REDACTED]
Addendum: Pathologist, [REDACTED]
Addendum Final: Pathologist, [REDACTED]

Source: NCI Genomic Data Commons file 8a373c1f-a29a-476c-a409-46cc1a6df637 (TCGA-HL-7533.2B99C03F-BFC5-47AA-BBD4-76B82E813280.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).